Somatic mutation profile of tumor specimen TCGA-BF-AAOU-01A (aliquot TCGA-BF-AAOU-01A-12D-A397-08) from TCGA case TCGA-BF-AAOU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 73.2 years (26,750 days).
Specimen TCGA-BF-AAOU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17fcc68c-f0ee-4491-9a62-f6504827da83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAOU-10A (Blood Derived Normal), aliquot TCGA-BF-AAOU-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d67f1878-1b10-41d2-9a78-0557604d9c4d

The open-access MAF lists 397 somatic variants for this specimen: 254 protein-altering or splice-affecting, 138 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 232, Silent 138, Nonsense Mutation 15, Splice Region 4, Intron 2, Splice Site 2, RNA 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.6376G>A p.E2126K (on ENST00000272895 / NM_173076.3; = p.E1808K on NM_015657.3) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.91); catalogued as COSV55950272; called by muse, mutect2, varscan2
- ABCA12 | c.845T>A p.L282Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs1387204579, COSV99788971; called by muse, varscan2
- ABCA13 | c.9311C>T p.S3104F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71283997; called by muse, mutect2, varscan2
- ABCC9 | c.4205C>T p.S1402F | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as CM141611, COSV53976423, COSV99684967; called by muse, mutect2, varscan2
- AC005324.2 | c.814A>T p.M272L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100371778; called by muse, mutect2, varscan2
- ACAN | c.4472C>T p.P1491L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61363443, COSV61364084; called by muse, mutect2, varscan2
- ADAD2 | c.1208G>A p.W403* (on ENST00000315906 / NM_001145400.2; = p.W485* on NM_139174.4) | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs1172591320, COSV99235156; called by muse, mutect2, varscan2
- ADAM18 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779557988, COSV55844959; called by muse, mutect2, varscan2
- ADCY10 | c.4328C>T p.S1443F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63239702; called by muse, mutect2, varscan2
- ADGRL2 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs1487870704, COSV54650244, COSV99587694; called by muse, mutect2, varscan2
- AHCYL1 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.412); catalogued as COSV100779491; called by muse, mutect2, varscan2
- ALKBH1 | c.272A>T p.Y91F | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99380470; called by muse, mutect2, varscan2
- ANGEL1 | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV99200342; called by muse, mutect2, varscan2
- ANGPT1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as rs867964520, COSV52431619, COSV99864298; called by muse, mutect2, varscan2
- ANKS1B | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as rs745539676, COSV61335090; called by muse, mutect2, varscan2
- ARHGAP15 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV99709255; called by muse, mutect2, varscan2
- ARHGEF11 | c.2332C>T p.L778F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100168362; called by muse, mutect2, varscan2
- ARSF | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV100839454; called by muse, mutect2, varscan2
- ASTN1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.747); catalogued as rs778285217, COSV99920869; called by muse, mutect2, varscan2
- ATAD2B | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174698065, COSV99477191; called by muse, mutect2
- ATAD5 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as COSV100429763; called by muse, mutect2, varscan2
- ATP2B3 | c.3179C>T p.T1060I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV99683537; called by muse, mutect2, varscan2
- ATP5MC2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV100100960; called by muse, mutect2, varscan2
- BCLAF1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs112571718; called by muse, mutect2
- BCOR | c.2667A>C p.K889N | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100653042; called by muse, mutect2, varscan2
- BLM | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs777938065, COSV100757068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP1 | c.579G>A p.K193= | Splice Region (SNP) | VAF 21/94 reads (22%) | catalogued as COSV99774818; called by muse, mutect2, varscan2
- BRINP3 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1202690091, COSV66543986; called by muse, mutect2, varscan2
- C16orf78 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1291251356, COSV54555372; called by muse, mutect2, varscan2
- C2CD3 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs748807026, COSV100486351; called by muse, mutect2, varscan2
- C4BPA | c.1772C>G p.S591C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.315); catalogued as COSV100891170, COSV65536219; called by muse, mutect2, varscan2
- CACNA1F | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as rs782157619, COSV100544519; called by muse, mutect2
- CACNA1S | c.4787G>A p.G1596E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.151); catalogued as COSV62935856; called by muse, mutect2, varscan2
- CADPS | c.2825C>T p.P942L | Missense Mutation (SNP) | VAF 129/236 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV99336699; called by muse, mutect2, varscan2
- CBLB | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.275); catalogued as COSV99912962; called by muse, mutect2
- CCDC141 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs865980981, COSV55377174; called by muse, mutect2, varscan2
- CCDC186 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV100991000; called by muse, mutect2, varscan2
- CCHCR1 | c.1387C>T p.R463* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as rs767959194, COSV100885594; called by muse, mutect2, varscan2
- CD300LG | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV99517300; called by muse, mutect2, varscan2
- CD4 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.618); catalogued as rs200486856, COSV99163707; called by muse, mutect2, varscan2
- CD72 | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99427336; called by muse, mutect2, varscan2
- CDC42EP1 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1366955370, COSV99312404; called by muse, mutect2, varscan2
- CDH11 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs374274441, COSV99217594; called by muse, mutect2, varscan2
- CDX1 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV99199301; called by muse, mutect2, varscan2
- CEACAM5 | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99703792; called by muse, mutect2, varscan2
- CERCAM | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV100863887; called by muse, mutect2, varscan2
- CERKL | c.1102C>T p.P368S (on ENST00000339098 / NM_001030311.2; = p.P342S on NM_201548.5) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1253663781, COSV100183329; called by muse, mutect2, varscan2
- CFAP161 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV99715398; called by muse, mutect2, varscan2
- CFH | c.3208G>A p.G1070S | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.792); catalogued as COSV100809125; called by muse, mutect2, varscan2
- CLCN5 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1569540513, COSV100259700; called by muse, mutect2, varscan2
- CNTN4 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68570297; called by muse, mutect2, varscan2
- CNTN4 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100639015, COSV100639120; called by muse, mutect2, varscan2
- CNTNAP2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.845); catalogued as rs956320440, COSV100674155, COSV62150880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL28A1 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs141928495, COSV68081743; called by muse, mutect2, varscan2
- COL4A4 | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.029); catalogued as COSV100306440; called by muse, mutect2, varscan2
- COL5A2 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66415380; called by muse, mutect2, varscan2
- CPNE3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99547331; called by muse, mutect2, varscan2
- CPXM1 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.348); catalogued as rs963797346, COSV101013694; called by muse, mutect2, varscan2
- CR1 | c.3388C>T p.P1130S | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100887445; called by muse, mutect2, varscan2
- CSMD3 | c.2225G>A p.G742E (on ENST00000297405 / NM_001363185.1; = p.G638E on NM_052900.3) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52230737; called by muse, mutect2, varscan2
- CUX2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV55626328; called by muse, mutect2, varscan2
- CXCR1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751280061, COSV55281680; called by muse, mutect2, varscan2
- CXCR2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV59282035; called by muse, mutect2, varscan2
- CYBB | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101059675, COSV101059702; called by muse, mutect2, varscan2
- CYC1 | c.563C>G p.A188G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); catalogued as COSV100010279, COSV59644654; called by muse, mutect2, varscan2
- DCAF8L1 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101491423; called by muse, mutect2, varscan2
- DCHS1 | c.5177G>A p.R1726K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1207924250, COSV100201713; called by muse, mutect2
- DCLK3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV69362420; called by muse, mutect2, varscan2
- DDX4 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100737389; called by muse, mutect2, varscan2
- DIP2C | c.3484C>T p.R1162C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs767258769, COSV55153642; called by muse, mutect2, varscan2
- DMD | c.8714G>A p.R2905Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs267606433, COSV58905668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH9 | c.8876G>A p.G2959E | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52350716; called by muse, mutect2, varscan2
- DNMBP | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1224441447, COSV60620828; called by muse, mutect2, varscan2
- DPP6 | c.1913C>T p.A638V (on ENST00000377770 / NM_001364500.2; = p.A576V on NM_001936.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1179208262, COSV100123905; called by muse, mutect2, varscan2
- DYM | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as rs756877451, COSV53980097; called by muse, mutect2, varscan2
- EHMT2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100977148; called by muse, mutect2, varscan2
- ELOA2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs772917421, COSV55293782; called by muse, mutect2, varscan2
- ERICH3 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs1388345581, COSV100443769; called by muse, mutect2, varscan2
- EXPH5 | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs375478139; called by muse, mutect2, varscan2
- FABP2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370366662; called by muse, mutect2, varscan2
- FAM83C | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as rs1267976399, COSV65583446; called by muse, mutect2, varscan2
- FAP | c.1363T>A p.F455I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99501912; called by muse, mutect2
- FBN3 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs144832713; called by muse, mutect2, varscan2
- FCRL5 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100708668; called by muse, mutect2, varscan2
- FLG | c.8207G>A p.G2736E | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.841); catalogued as rs775902916, COSV100910313; called by mutect2, varscan2
- FLG | c.7378G>A p.D2460N | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.066); catalogued as COSV100911182; called by muse, mutect2, varscan2
- FLG2 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV66168916, COSV66170068; called by muse, mutect2, varscan2
- FLNC | c.3836C>T p.S1279F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV57951888; called by muse, mutect2, varscan2
- FLNC | c.7549G>A p.G2517R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV100367785; called by muse, mutect2, varscan2
- FNDC1 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.226); catalogued as rs267600879, COSV51944087; called by muse, mutect2, varscan2
- GABRB2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554093891, COSV50913762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAPVD1 | c.3347C>T p.S1116F (on ENST00000394104; = p.S1125F on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1249059421, COSV99782855; called by muse, mutect2, varscan2
- GATA2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100350711, COSV100351066; called by muse, mutect2, varscan2
- GBA3 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as COSV72437971; called by muse, mutect2, varscan2
- GDPD1 | c.684A>T p.E228D | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99404895; called by muse, mutect2, varscan2
- GJA5 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.313); catalogued as COSV99605412; called by muse, mutect2, varscan2
- GRIA4 | c.1269+1G>A p.X423_splice | Splice Site (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99229788; called by muse, mutect2, varscan2
- HDAC9 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs753279370, COSV67768006, COSV67776035; called by muse, mutect2, varscan2
- HIF3A | c.295G>A p.V99M (on ENST00000377670 / NM_152795.4; = p.V97M on NM_152794.4) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52196399; called by muse, mutect2, varscan2
- HLA-DQA2 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs754332079, COSV100890682; called by muse, varscan2
- IGDCC4 | c.1578C>T p.V526= | Splice Region (SNP) | VAF 10/33 reads (30%) | catalogued as rs201579916, COSV100732762; called by muse, mutect2, varscan2
- IKZF1 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100498136; called by muse, mutect2
- INMT | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50000077; called by muse, mutect2
- INSIG1 | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100452897; called by muse, mutect2, varscan2
- IPO5 | c.3141G>T p.M1047I | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs770196627, COSV99847080; called by muse, mutect2, varscan2
- ITGA11 | c.1372A>T p.T458S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV100241166; called by muse, mutect2
- ITGA2B | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs75998071, COSV99288666; called by muse, mutect2, varscan2
- ITGAX | c.2576G>A p.W859* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99191537; called by muse, mutect2, varscan2
- JCAD | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as COSV100948184, COSV64760969; called by muse, varscan2
- KATNIP | c.3911C>T p.A1304V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.676); catalogued as rs1432622771, COSV99850296; called by muse, mutect2, varscan2
- KCNH8 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.596); catalogued as COSV100109012; called by muse, mutect2, varscan2
- KCNJ2 | c.978T>A p.Y326* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99696267; called by muse, mutect2, varscan2
- KHDRBS2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV99832033; called by muse, mutect2, varscan2
- KIF19 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100738995; called by muse, mutect2, varscan2
- KIF25 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100596275; called by muse, mutect2, varscan2
- KRT26 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV59415517; called by muse, mutect2, varscan2
- KRTAP9-4 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as rs1311310195, COSV100484854; called by muse, varscan2
- LAMP5 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV99855495; called by muse, mutect2, varscan2
- LILRB5 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV60256405; called by muse, mutect2, varscan2
- LRBA | c.2785A>G p.K929E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV100841116; called by muse, mutect2, varscan2
- LRFN2 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs571421943, COSV57826305; called by muse, mutect2, varscan2
- LTBP4 | c.3308G>T p.G1103V (on ENST00000308370 / NM_001042544.1; = p.G1066V on NM_003573.2) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99183066; called by muse, mutect2, varscan2
- MAPK4 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.107); catalogued as rs762992386, COSV101245246; called by muse, mutect2, varscan2
- MAPK8 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100827392; called by muse, mutect2, varscan2
- MC5R | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100228966; called by muse, mutect2, varscan2
- MEX3D | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1406414222, COSV101183474, COSV101183557; called by muse, mutect2, varscan2
- MMP12 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100404856; called by muse, mutect2, varscan2
- MMP2 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1435149653, COSV99527546; called by muse, mutect2, varscan2
- MUC16 | c.12055G>A p.D4019N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.263); catalogued as COSV101198819; called by muse, mutect2, varscan2
- MUC16 | c.4942G>A p.A1648T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV101198820; called by muse, mutect2, varscan2
- MYH6 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100676382; called by muse, mutect2, varscan2
- MYH7 | c.3898C>T p.Q1300* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100805838; called by muse, mutect2, varscan2
- MYO5B | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs1485458017, COSV53235564; called by muse, mutect2, varscan2
- MYT1L | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.71); catalogued as rs1465709527, COSV101219478; called by muse, mutect2, varscan2
- NBAS | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs767698268, COSV55724060, COSV55736640; called by muse, mutect2, varscan2
- NBEAL1 | c.5731A>G p.T1911A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs1319582076, COSV101355426; called by muse, mutect2, varscan2
- NCKIPSD | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99583784; called by muse, mutect2, varscan2
- NDN | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs750065030, COSV100086393, COSV59361564; called by muse, mutect2, varscan2
- NEBL | c.1965C>T p.L655= | Splice Region (SNP) | VAF 50/109 reads (46%) | catalogued as COSV101009143; called by muse, mutect2, varscan2
- NEURL4 | c.3299C>T p.P1100L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100222801; called by muse, mutect2, varscan2
- NFASC | c.2675C>T p.P892L (on ENST00000339876 / NM_001378329.1; = p.P995L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV58361482; called by muse, mutect2, varscan2
- NMS | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as rs908638108, COSV100966563; called by muse, mutect2, varscan2
- NUDT16L1 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs1406478189, COSV99273881; called by muse, mutect2
- NUP210L | c.5302C>T p.P1768S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV55144880; called by muse, mutect2, varscan2
- NYAP2 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56003594; called by muse, mutect2, varscan2
- OIP5 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs374055137; called by muse, mutect2, varscan2
- OPRM1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100000777; called by muse, mutect2, varscan2
- OR2W1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1226192074, COSV65851432, COSV65851562, COSV65852021; called by muse, mutect2, varscan2
- OR2W3 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100831628; called by muse, mutect2, varscan2
- OR4N2 | c.797C>A p.P266Q | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV60051203, COSV60053350; called by muse, mutect2, varscan2
- OR5L2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65724647; called by muse, mutect2, varscan2
- OR8H3 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1000017902, COSV100539197, COSV57912419; called by muse, mutect2, varscan2
- OR9G4 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265055; called by muse, mutect2
- OTOA | c.1779G>A p.M593I (on ENST00000286149; = p.M579I on NM_144672.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53763511, COSV99623983; called by muse, mutect2, varscan2
- PAAF1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV100142377; called by muse, mutect2, varscan2
- PAK3 | c.538C>T p.P180S (on ENST00000262836 / NM_001324328.2; = p.P165S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99456784; called by muse, mutect2, varscan2
- PALM | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99214365; called by muse, mutect2, varscan2
- PCARE | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs754999394, COSV100527408; called by muse, mutect2, varscan2
- PCDHB9 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.099); catalogued as COSV53375009; called by muse, mutect2, varscan2
- PCDHGA3 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.139); catalogued as COSV53935665; called by muse, mutect2, varscan2
- PCLO | c.14005G>A p.G4669R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1246794977, COSV100429087; called by muse, mutect2, varscan2
- PCNX2 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as rs781497332, COSV99266538; called by muse, mutect2, varscan2
- PEG3 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV55637343, COSV99687906; called by muse, mutect2, varscan2
- PLIN5 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101113453; called by muse, mutect2
- PLXNA4 | c.4009G>A p.D1337N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV58159692; called by muse, mutect2, varscan2
- PLXNB3 | c.2539C>A p.P847T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as COSV100737221; called by muse, mutect2, varscan2
- PMFBP1 | c.2548G>A p.E850K (on ENST00000537465; = p.E845K on NM_031293.3) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.058); catalogued as rs1474370762, COSV99400471; called by muse, mutect2, varscan2
- PPEF1 | c.726del p.X242_splice | Splice Site (DEL) | VAF 7/47 reads (15%) | catalogued as COSV62996880; called by mutect2, varscan2
- PRKCB | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207487721, COSV57767885; called by muse, mutect2, varscan2
- PROM2 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 41/122 reads (34%) | catalogued as rs1276201019, COSV100468774; called by muse, mutect2, varscan2
- PRPH2 | c.504C>A p.N168K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100027994; called by muse, mutect2, varscan2
- PRSS58 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs149180097, COSV73488438; called by muse, mutect2, varscan2
- PSG6 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs1345906862, COSV51831255; called by muse, mutect2, varscan2
- PTPRK | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as rs777523499, COSV100950501, COSV100950565; called by muse, mutect2, varscan2
- REG3G | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99709302; called by muse, mutect2, varscan2
- RGS22 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV62667466; called by muse, mutect2, varscan2
- RIC3 | c.1100G>A p.G367D (on ENST00000309737 / NM_001206671.4; = p.G366D on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); catalogued as rs753035547, COSV100111790; called by muse, mutect2, varscan2
- RIMKLA | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); catalogued as COSV101290559, COSV68910003; called by muse, mutect2, varscan2
- RNF43 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs150996748, COSV68458126; called by muse, mutect2, varscan2
- RNF6 | c.1475G>C p.G492A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100644599; called by muse, mutect2, varscan2
- RPL26L1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99442446; called by muse, mutect2, varscan2
- RUNX1 | c.812C>A p.P271Q (on ENST00000344691 / NM_001001890.3; = p.P298Q on NM_001754.5) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.4); catalogued as COSV100276801; called by muse, mutect2, varscan2
- S1PR1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100541507; called by muse, mutect2, varscan2
- SALL1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99172029; called by muse, mutect2, varscan2
- SCML2 | c.2090G>A p.G697E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52621979; called by muse, mutect2, varscan2
- SEMA6B | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014718; called by muse, mutect2, varscan2
- SFPQ | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61758424; called by muse, mutect2, varscan2
- SH3BP5L | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100821982; called by muse, mutect2, varscan2
- SH3KBP1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV101115799; called by muse, mutect2, varscan2
- SHANK1 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV53243427; called by muse, mutect2, varscan2
- SIDT2 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99637350; called by muse, mutect2, varscan2
- SLC13A5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99545778; called by muse, mutect2, varscan2
- SLC1A1 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs774326354, COSV52059172; called by muse, mutect2, varscan2
- SLC41A3 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 81/131 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100259448; called by muse, mutect2, varscan2
- SMARCA1 | c.3161C>T p.S1054F | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100946430; called by muse, mutect2, varscan2
- SMG8 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99958728; called by muse, mutect2, varscan2
- SNX30 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100953796; called by muse, mutect2, varscan2
- SP2 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100947152; called by muse, mutect2, varscan2
- SPATA31E1 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV100350100; called by muse, mutect2, varscan2
- SPTBN4 | c.7607G>A p.G2536D | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1188605557, COSV99398996; called by muse, mutect2, varscan2
- SRRM1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs774225218, COSV100104259; called by muse, mutect2, varscan2
- SSTR4 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs1036826418, COSV99658463; called by muse, mutect2, varscan2
- STRN4 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1252061351, COSV99623453, COSV99623878; called by muse, mutect2, varscan2
- SUMF1 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as COSV99794547; called by muse, mutect2, varscan2
- SYNE1 | c.3313C>T p.L1105F (on ENST00000367255 / NM_182961.4; = p.L1112F on NM_033071.3) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV99557054; called by muse, mutect2, varscan2
- SYT11 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100851288; called by muse, mutect2, varscan2
- TAF1L | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV99644306; called by muse, mutect2, varscan2
- TAOK1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.271); catalogued as COSV99913704; called by muse, mutect2, varscan2
- TAS1R1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.268); catalogued as rs868758992, COSV100039544; called by muse, mutect2, varscan2
- TDRD6 | c.3754C>T p.P1252S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100287325; called by muse, mutect2, varscan2
- TDRD6 | c.3755C>T p.P1252L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1052863482, COSV100287326; called by muse, mutect2, varscan2
- TET3 | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101327694; called by muse, mutect2, varscan2
- TGM6 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99171716; called by muse, mutect2, varscan2
- TGM6 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99171717; called by muse, mutect2, varscan2
- THBS4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100644218; called by muse, mutect2
- THEMIS | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.209); catalogued as rs1049532553, COSV64069628, COSV64075353; called by muse, mutect2, varscan2
- THSD7A | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051817932, COSV70264321; called by muse, mutect2, varscan2
- TMEM131 | c.3611C>T p.S1204F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV99487036; called by muse, mutect2, varscan2
- TMEM132D | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67162726; called by muse, mutect2, varscan2
- TNIK | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as COSV99455888; called by muse, mutect2, varscan2
- TNRC6A | c.3158A>G p.E1053G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100169625; called by muse, mutect2
- TPCN1 | c.2201C>T p.S734F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV100136532; called by muse, mutect2, varscan2
- TRIM58 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV63569308; called by muse, mutect2, varscan2
- TRIOBP | c.3515C>T p.P1172L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100730739; called by muse, mutect2
- TSPAN11 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs762034372, COSV99666715; called by muse, mutect2, varscan2
- TTBK1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.636); catalogued as COSV99444008; called by muse, mutect2
- TTC12 | c.1988C>A p.A663D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100132928, COSV59098098; called by muse, mutect2, varscan2
- TTN | c.39412G>A p.E13138K (on ENST00000591111; = p.E5714K on NM_003319.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | PolyPhen probably damaging (0.994); catalogued as COSV60386201; called by muse, mutect2, varscan2
- UACA | c.4192G>A p.E1398K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100537371; called by muse, mutect2
- UBE2E1 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100135154; called by muse, mutect2, varscan2
- WBP11 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.222); catalogued as COSV99660589; called by muse, mutect2, varscan2
- WDR33 | c.3493C>T p.P1165S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100459729; called by muse, mutect2, varscan2
- WIPF1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs966184436, COSV99768211; called by muse, mutect2, varscan2
- XDH | c.1720G>T p.V574L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV101052107; called by muse, mutect2, varscan2
- XDH | c.1719G>A p.M573I | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs777603147, COSV101052109; called by muse, mutect2, varscan2
- XIRP2 | c.5362G>A p.D1788N (on ENST00000628543; = p.D1963N on NM_152381.6) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99740171; called by muse, mutect2, varscan2
- YLPM1 | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as rs895360579, COSV53107548; called by muse, varscan2
- ZEB2 | c.2740C>T p.Q914* | Nonsense Mutation (SNP) | VAF 42/139 reads (30%) | catalogued as rs1038288183, COSV100355461; called by muse, mutect2, varscan2
- ZFHX4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.734); catalogued as COSV51465610; called by muse, mutect2, varscan2
- ZFYVE9 | c.187A>G p.N63D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99819576; called by muse, mutect2, varscan2
- ZHX2 | c.770A>G p.K257R | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58710141; called by muse, mutect2, varscan2
- ZNF251 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs200509361, COSV99478228, COSV99478236; called by muse, mutect2, varscan2
- ZNF341 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as COSV100677782; called by muse, mutect2, varscan2
- ZNF423 | c.2834G>A p.R945Q (on ENST00000563137 / NM_001379286.1; = p.R937Q on NM_015069.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as COSV52205964; called by muse, mutect2, varscan2
- ZNF439 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100397419; called by muse, mutect2, varscan2
- ZNF536 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV100834885, COSV100835746, COSV62824343; called by muse, mutect2, varscan2
- ZNF607 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.711); catalogued as COSV100777844; called by muse, mutect2, varscan2
- ZNF99 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68056153; called by muse, mutect2
- ZP2 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV54812203; called by muse, mutect2, varscan2
- ZYX | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1367467820, COSV100503616; called by muse, mutect2, varscan2
- KRAS | c.186_187insAAGTACAGTGCAATGAGG p.E62_E63insKYSAMR | In Frame Ins (INS) | VAF 35/89 reads (39%) | called by muse*, mutect2, varscan2*
- PPEF1 | c.726G>A p.R242= | Splice Region (SNP) | VAF 8/46 reads (17%) | called by mutect2, varscan2
- WASHC2C | c.3431C>T p.S1144F (on ENST00000336378; = p.S1123F on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF135 | c.497G>A p.G166E (on ENST00000313434 / NM_001289401.2; = p.G178E on NM_003436.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.976); called by muse, mutect2
- ABCB11 | c.984C>T p.F328= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs769564355, COSV55591589; called by muse, mutect2, varscan2
- ACAD10 | c.1272C>T p.T424= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100563939; called by muse, mutect2, varscan2
- ADAMTS2 | c.843C>T p.F281= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as COSV99201138; called by muse, mutect2, varscan2
- ADAMTS9 | c.4216C>T p.L1406= | Silent (SNP) | VAF 117/184 reads (64%) | catalogued as COSV99898991; called by muse, mutect2, varscan2
- ADH6 | c.867C>T p.V289= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99422062; called by muse, mutect2, varscan2
- AHNAK | c.15765C>T p.V5255= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV57207213; called by muse, mutect2, varscan2
- AL121899.2 | c.2040C>T p.I680= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs1409409273, COSV101198419; called by muse, mutect2, varscan2
- ALCAM | c.120C>T p.I40= | Silent (SNP) | VAF 44/80 reads (55%) | catalogued as rs752455089, COSV100064457; called by muse, mutect2, varscan2
- AMPD2 | c.1173C>T p.I391= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs562274293, COSV56646626; called by muse, mutect2, varscan2
- BRD1 | c.861C>T p.D287= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs752269283, COSV99349411; called by muse, mutect2, varscan2
- CA3 | c.312C>T p.G104= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99570599; called by muse, mutect2, varscan2
- CACNA2D2 | c.1563C>T p.I521= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV99817139; called by muse, mutect2, varscan2
- CAMTA2 | c.1089G>A p.E363= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100772506; called by muse, mutect2, varscan2
- CCDC69 | c.621G>A p.E207= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV62599234, COSV62599672; called by muse, mutect2, varscan2
- CD163 | c.1428G>A p.R476= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100775743; called by muse, mutect2, varscan2
- CHKB | c.621C>T p.L207= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs372742172; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNGA2 | c.1101C>T p.I367= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs141471697, COSV61704820; called by muse, mutect2, varscan2
- CNOT3 | c.1428C>T p.A476= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99651616; called by muse, mutect2, varscan2
- COL4A4 | c.777G>A p.L259= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100306441; called by muse, mutect2, varscan2
- COL6A2 | c.1911C>T p.F637= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs746339542, COSV56007675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTCF | c.438C>T p.G146= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV99864401, COSV99864707; called by muse, mutect2, varscan2
- CYP3A7 | c.657C>T p.F219= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as rs375990155; called by muse, mutect2, varscan2
- CYP7B1 | c.1296G>A p.G432= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs1342380224, COSV59592573; called by muse, mutect2, varscan2
- DDX4 | c.1737G>A p.R579= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV61757687; called by muse, mutect2, varscan2
- DNAH5 | c.9678G>A p.A3226= | Silent (SNP) | VAF 120/201 reads (60%) | catalogued as rs547729937, COSV54207337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPF3 | c.36C>T p.L12= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs748266515, COSV100818448; called by muse, varscan2
- DPYSL2 | c.1674C>T p.I558= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs780843208, COSV100233684; called by muse, mutect2, varscan2
- DSCAM | c.5202G>A p.R1734= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs777965263, COSV68037693; called by muse, mutect2, varscan2
- ECHS1 | c.495C>T p.I165= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100881882; called by muse, mutect2, varscan2
- EDIL3 | c.1374C>T p.I458= | Silent (SNP) | VAF 49/100 reads (49%) | catalogued as COSV99675329; called by muse, mutect2, varscan2
- EHMT2 | c.1521G>A p.L507= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100977149; called by muse, mutect2, varscan2
- ELMOD3 | c.670C>T p.L224= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1339094792, COSV100226134; called by muse, mutect2, varscan2
- ENTPD3 | c.654G>A p.L218= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100088531; called by muse, mutect2, varscan2
- ENTPD7 | c.985C>T p.L329= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100978364; called by muse, mutect2, varscan2
- EPHA8 | c.2631G>A p.K877= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99384439; called by muse, mutect2, varscan2
- FAM120A | c.2061G>A p.R687= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99464854; called by muse, mutect2, varscan2
- FAM83F | c.588G>A p.L196= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100328872; called by muse, mutect2, varscan2
- FAP | c.1365C>T p.F455= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99501907; called by muse, mutect2
- FBXO15 | c.477C>T p.I159= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1434105923, COSV99503148; called by muse, mutect2, varscan2
- FKBP10 | c.615C>T p.V205= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs143446005; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMO5 | c.960G>A p.E320= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV99566824; called by muse, mutect2, varscan2
- FPR2 | c.435G>A p.V145= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs747494377, COSV100389185; called by muse, mutect2, varscan2
- GABRE | c.504C>T p.I168= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV64819356; called by muse, mutect2, varscan2
- GALNT13 | c.1140C>T p.F380= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV67216729; called by muse, mutect2, varscan2
- GBX2 | c.495C>T p.S165= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1266145891, COSV100103466; called by muse, mutect2, varscan2
- GFUS | c.873C>T p.T291= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99643353; called by muse, mutect2, varscan2
- GNG11 | c.9C>T p.A3= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1423830724, COSV99949327; called by muse, mutect2, varscan2
- GPR148 | c.141C>T p.S47= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99998538; called by muse, mutect2, varscan2
- GPS1 | c.855C>T p.S285= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100135897; called by muse, mutect2
- GRIN3A | c.1392C>T p.F464= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as COSV62451106; called by muse, mutect2, varscan2
- HIRA | c.3009C>T p.L1003= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99600053; called by muse, mutect2
- HSH2D | c.999G>A p.E333= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1056671548, COSV53737163, COSV99507146; called by muse, mutect2, varscan2
- HYDIN | c.10632C>T p.I3544= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV101153680; called by muse, mutect2, varscan2
- IGHV3-53 | c.183G>A p.G61= | Silent (SNP) | VAF 51/274 reads (19%) | called by muse, mutect2, varscan2
- IGKV1-16 | c.189G>A p.G63= | Silent (SNP) | VAF 72/240 reads (30%) | called by muse, varscan2
- IL1RL2 | c.372T>C p.G124= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99960373; called by muse, mutect2, varscan2
- ITGA11 | c.1374C>A p.T458= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100241164, COSV59877857; called by muse, mutect2
- KCNH1 | c.978G>A p.G326= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV55103137; called by muse, mutect2, varscan2
- KIAA1217 | c.2115C>T p.V705= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100286321; called by muse, mutect2, varscan2
- KIF21B | c.1761G>A p.A587= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as rs750670224, COSV100144036; called by muse, mutect2, varscan2
- KIF26B | c.6099G>A p.A2033= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs755672216, COSV63652538; called by muse, mutect2, varscan2
- KIR3DL3 | c.885C>T p.G295= | Silent (SNP) | VAF 79/254 reads (31%) | called by muse, mutect2, varscan2
- KRT36 | c.12G>A p.Q4= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100057398, COSV60204595; called by muse, mutect2, varscan2
- KRT73 | c.90C>T p.S30= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs758846092, COSV99988354; called by muse, mutect2, varscan2
- LGR4 | c.1641C>T p.F547= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV101004018, COSV64863614; called by muse, mutect2, varscan2
- LHX5 | c.531C>A p.G177= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99922414; called by muse, mutect2, varscan2
- LOXL2 | c.1707C>T p.F569= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV101207786; called by muse, mutect2
- LRG1 | c.561C>T p.F187= | Silent (SNP) | VAF 50/165 reads (30%) | catalogued as COSV56703278; called by muse, mutect2, varscan2
- LRP2 | c.4905G>A p.V1635= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99787145; called by muse, mutect2, varscan2
- MAP3K15 | c.2307C>T p.I769= | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as rs757714655, COSV58837127; called by muse, mutect2, varscan2
- MAP7 | c.1143G>A p.E381= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs1337646101, COSV63424259; called by muse, mutect2, varscan2
- MARF1 | c.5076C>T p.I1692= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100705683, COSV60027940; called by muse, mutect2, varscan2
- MDM1 | c.720T>C p.G240= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as COSV100291703; called by muse, mutect2, varscan2
- MGAT4A | c.123C>T p.F41= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV53846169; called by muse, mutect2, varscan2
- MUC21 | c.609C>T p.T203= | Silent (SNP) | VAF 50/202 reads (25%) | catalogued as COSV100888843; called by muse, varscan2
- MUSK | c.2217G>A p.V739= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as rs1358119507, COSV99503842; called by muse, mutect2, varscan2
- MYH2 | c.5121C>T p.I1707= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs780525531, COSV55436745; called by muse, mutect2, varscan2
- MYH2 | c.1818G>A p.E606= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV99063175, COSV99819592; called by muse, mutect2, varscan2
- NFASC | c.2676C>T p.P892= (on ENST00000339876 / NM_001378329.1; = p.P995= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs148850236; called by muse, mutect2, varscan2
- NRK | c.3513C>T p.F1171= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as rs765030639, COSV54602949; called by muse, mutect2, varscan2
- NUDT18 | c.885C>T p.F295= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99248806; called by muse, mutect2, varscan2
- OLFML1 | c.618G>A p.K206= | Silent (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- OR2A2 | c.483C>T p.L161= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV101286633; called by muse, mutect2, varscan2
- OR2G3 | c.645C>T p.S215= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV60682253; called by muse, mutect2, varscan2
- OR5AC2 | c.924G>A p.R308= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs1426415501, COSV100684385; called by muse, mutect2, varscan2
- OR5H15 | c.492C>T p.F164= | Silent (SNP) | VAF 54/99 reads (55%) | catalogued as COSV100736636, COSV62947913; called by muse, mutect2, varscan2
- OR6C74 | c.486C>T p.L162= | Silent (SNP) | VAF 61/101 reads (60%) | catalogued as rs551720956, COSV100667709; called by muse, mutect2, varscan2
- OR6Y1 | c.975T>C p.S325= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100225300; called by muse, mutect2, varscan2
- PACSIN2 | c.1170G>A p.K390= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV54316047; called by muse, mutect2, varscan2
- PADI3 | c.873C>T p.F291= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs780639796, COSV100968435; called by muse, mutect2, varscan2
- PASD1 | c.816C>T p.F272= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV100949182; called by muse, mutect2, varscan2
- PGA3 | c.453C>T p.V151= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1244841151, COSV100337327; called by mutect2, varscan2
- PHKA2 | c.471C>T p.F157= | Silent (SNP) | VAF 51/206 reads (25%) | catalogued as COSV101176825; called by muse, mutect2, varscan2
- PIGZ | c.336G>A p.E112= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs758132825, COSV99433709; called by muse, varscan2
- PIK3C2B | c.1947T>C p.Y649= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100916021; called by muse, mutect2, varscan2
- PIP | c.105C>T p.I35= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99344086; called by muse, mutect2, varscan2
- PPARGC1A | c.1374C>T p.I458= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1280177769, COSV99337553, COSV99337712; called by muse, mutect2, varscan2
- PRAMEF14 | c.1311G>A p.L437= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as rs889708946, COSV100577278; called by muse, mutect2, varscan2
- PREX2 | c.4731G>A p.A1577= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs756670148, COSV55752329; called by muse, mutect2, varscan2
- PRKCG | c.1296C>T p.F432= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs778076446, COSV54724638; called by muse, mutect2, varscan2
- PROM2 | c.34C>T p.L12= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1394356198, COSV100468771; called by muse, mutect2, varscan2
- PROX2 | c.507G>A p.G169= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101507797; called by muse, mutect2, varscan2
- PSG5 | c.660G>A p.R220= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as COSV100742604; called by muse, varscan2
- PTPRS | c.3384C>T p.V1128= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs150297565; called by muse, mutect2, varscan2
- REST | c.226C>T p.L76= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100470761; called by muse, mutect2, varscan2
- RPE65 | c.918T>G p.T306= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV99253696; called by muse, mutect2, varscan2
- SALL1 | c.1212C>T p.S404= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs775269148, COSV99172049; called by muse, mutect2, varscan2
- SCN2A | c.3459G>A p.E1153= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs548830804, COSV99330645; called by muse, mutect2, varscan2
- SCN2A | c.5004C>T p.F1668= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs886044285, COSV99330649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3E | c.474G>A p.L158= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1273572732, COSV100317807, COSV100318955; called by muse, mutect2, varscan2
- SGCG | c.810G>A p.G270= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99522701; called by muse, mutect2, varscan2
- SLC1A6 | c.1077C>T p.P359= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99693509; called by muse, mutect2, varscan2
- SLC22A1 | c.1014C>T p.F338= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100266544; called by muse, mutect2, varscan2
- SLC22A10 | c.1137C>T p.F379= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs564171817, COSV60419818; called by muse, mutect2, varscan2
- SLC25A35 | c.486G>A p.L162= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99873770; called by muse, mutect2, varscan2
- SLC46A3 | c.306C>T p.F102= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV57182961; called by muse, mutect2, varscan2
- ST18 | c.2943G>A p.E981= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99388793; called by muse, mutect2, varscan2
- TENM1 | c.1288C>T p.L430= | Silent (SNP) | VAF 39/168 reads (23%) | catalogued as COSV100949418; called by muse, mutect2, varscan2
- TENM2 | c.1782C>T p.F594= (on ENST00000518659 / NM_001122679.2; = p.F362= on NM_001080428.3) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV101318251; called by muse, mutect2, varscan2
- TKTL2 | c.351G>A p.P117= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs369284301; called by muse, mutect2, varscan2
- TMEM174 | c.87G>A p.Q29= | Silent (SNP) | VAF 35/199 reads (18%) | catalogued as COSV99703742; called by muse, mutect2, varscan2
- TOX3 | c.633C>T p.S211= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV54863776; called by muse, mutect2, varscan2
- TPCN1 | c.2202C>T p.S734= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100136534; called by muse, mutect2, varscan2
- TRHR | c.975G>A p.Q325= | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as COSV61236931; called by muse, mutect2, varscan2
- TRPA1 | c.1794G>A p.T598= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs772012081, COSV100083356; called by muse, mutect2, varscan2
- TSHZ2 | c.2631G>A p.L877= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100295624, COSV61587759; called by muse, mutect2, varscan2
- TTC12 | c.1989C>T p.A663= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs145542172; called by muse, mutect2, varscan2
- TXNDC5 | c.375C>T p.S125= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs145214714, COSV101124314; called by muse, mutect2, varscan2
- USP4 | c.2460C>T p.I820= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as rs1432750167, COSV55540412; called by muse, mutect2, varscan2
- VPS18 | c.219G>A p.K73= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99592370; called by muse, mutect2, varscan2
- WDTC1 | c.1659C>T p.I553= (on ENST00000319394 / NM_001276252.2; = p.I552= on NM_015023.5) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs143241417; called by muse, mutect2, varscan2
- YLPM1 | c.2055C>T p.Y685= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1468241378, COSV53123244, COSV99458996; called by muse, varscan2
- ZAN | c.2844C>T p.P948= | Silent (SNP) | VAF 47/212 reads (22%) | catalogued as COSV100769413, COSV61807180; called by muse, mutect2, varscan2
- ZFHX3 | c.399C>T p.I133= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs368497120; called by muse, mutect2, varscan2
- ZFPM2 | c.1917G>A p.G639= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101023080, COSV65874757; called by muse, mutect2, varscan2
- ZNF608 | c.2268C>T p.T756= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV60436621; called by muse, mutect2, varscan2
- ZNF831 | c.1872G>A p.G624= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs374469058, COSV100925887, COSV64038997; called by muse, mutect2, varscan2
- ZYX | c.390C>T p.P130= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100503617; called by muse, mutect2, varscan2
- ANK1 | c.5619+284G>A | Intron (SNP) | VAF 23/75 reads (31%) | catalogued as rs1165363773, COSV99224469; called by muse, mutect2, varscan2
- ARMC5 | c.1864+133C>T | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as rs765038485, COSV99192372; called by muse, mutect2, varscan2
- C20orf197 | n.480C>T | RNA (SNP) | VAF 15/67 reads (22%) | catalogued as rs867995695; called by muse, mutect2, varscan2
- SLC26A9 | c.*323G>A | 3'UTR (SNP) | VAF 7/73 reads (10%) | catalogued as rs1355465944, COSV100536147; called by muse, mutect2
- SNORD114-2 | n.49A>C | RNA (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
